Somatic mutation profile of tumor specimen TCGA-HT-7481-01A (aliquot TCGA-HT-7481-01A-11D-2024-08) from TCGA case TCGA-HT-7481, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 39.2 years (14,306 days).
Specimen TCGA-HT-7481-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8354b836-7a96-4988-9df5-c75464a1d294.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7481-10A (Blood Derived Normal), aliquot TCGA-HT-7481-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10e6eef7-92c2-4d06-aed8-8c000996b9c5

The open-access MAF lists 26 somatic variants for this specimen: 24 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 18, In Frame Del 5, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 17/92 reads (18%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NOTCH1 | c.1073_1075del p.Y358del | In Frame Del (DEL) | VAF 6/29 reads (21%) | hotspot (GDC flag); called by mutect2, varscan2
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 14/93 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIK3CA | c.3127A>G p.M1043V | Missense Mutation (SNP) | VAF 6/108 reads (6%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1057519936, COSV55879858, COSV55890961; ClinVar: likely pathogenic; called by muse, mutect2
- PIK3R1 | c.1135_1137del p.K379del (on ENST00000521381 / NM_181523.3; = p.K109del on NM_181504.4) | In Frame Del (DEL) | VAF 10/76 reads (13%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- CCN5 | c.148T>G p.C50G | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51939066; called by muse, mutect2, varscan2
- CD163 | c.3238C>T p.R1080W | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as rs749974365, COSV63130419; called by muse, mutect2, varscan2
- CPEB2 | c.2563A>T p.I855L | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52595127; called by muse, mutect2
- DNMT3A | c.776C>G p.A259G | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.422); catalogued as COSV53075050; called by muse, mutect2, varscan2
- FLRT3 | c.1882A>G p.S628G | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.079); catalogued as COSV54044609; called by muse, mutect2, varscan2
- FUBP1 | c.1758G>A p.W586* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV53937471; called by muse, mutect2, varscan2
- GK2 | c.719A>G p.Y240C | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1219183366, COSV62628227; called by muse, mutect2, varscan2
- H2BC7 | c.73_75del p.K25del | In Frame Del (DEL) | VAF 56/188 reads (30%) | catalogued as rs772306298; called by pindel, varscan2
- HRNR | c.2863T>C p.S955P | Missense Mutation (SNP) | VAF 96/399 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.725); catalogued as COSV64262220; called by muse, mutect2, varscan2
- KERA | c.515A>G p.D172G | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57131636; called by muse, mutect2, varscan2
- KIF6 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs780284536, COSV54677726; called by muse, mutect2, varscan2
- LMLN | c.1576C>G p.L526V | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV57604584; called by muse, mutect2, varscan2
- MAP3K4 | c.1591G>C p.D531H | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62337874; called by muse, mutect2, varscan2
- NETO1 | c.1423A>G p.I475V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.007); catalogued as rs1369865784, COSV55014513; called by muse, mutect2, varscan2
- NUP155 | c.2675A>G p.E892G (on ENST00000231498 / NM_153485.3; = p.E833G on NM_004298.4) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV51534123; called by muse, mutect2, varscan2
- TSHZ2 | c.3023C>T p.A1008V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754153089, COSV61588018; called by muse, mutect2, varscan2
- UGT2B28 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as rs1332568490, COSV100158574, COSV59434073; called by muse, mutect2, varscan2
- BACH2 | c.1590_1592del p.E530del | In Frame Del (DEL) | VAF 16/72 reads (22%) | called by pindel, varscan2
- TXNDC11 | c.2938_2940del p.K980del (on ENST00000356957 / NM_001303447.2; = p.K953del on NM_015914.7 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 5/57 reads (9%) | called by mutect2, pindel
- FSCB | c.1153C>A p.R385= | Silent (SNP) | VAF 13/159 reads (8%) | catalogued as COSV61219384; called by muse, mutect2
- RAB11FIP1 | c.585C>T p.S195= | Silent (SNP) | VAF 13/190 reads (7%) | catalogued as rs758439108, COSV54763351; called by muse, mutect2
